Somatic mutation profile of tumor specimen 0DIOKM from CCDI case PBBVWK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.2 years (811 days).
Specimen 0DIOKM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abda8a47-d830-435f-aef3-e2fd36a29463.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIOK1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2858039-57ca-464a-a7f3-5ddd4e344c60

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 3, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DLG5 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 19/598 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141342062; called by muse, mutect2
- FABP2 | c.79G>C p.V27L | Missense Mutation (SNP) | VAF 153/337 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMARCB1 | c.1006del p.A336Pfs*101 (on ENST00000263121; = p.A382Pfs*101 on NM_003073.5) | Frame Shift Del (DEL) | VAF 217/263 reads (83%) | called by mutect2, varscan2
- SOX3 | c.58T>A p.L20M | Missense Mutation (SNP) | VAF 352/818 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ADAMTS20 | c.3025C>T p.L1009= | Silent (SNP) | VAF 211/528 reads (40%) | catalogued as COSV67134718; called by muse, mutect2, varscan2
- DCHS1 | c.4212G>A p.A1404= | Silent (SNP) | VAF 234/502 reads (47%) | called by muse, mutect2, varscan2
- SMCR8 | c.2760C>T p.T920= | Silent (SNP) | VAF 177/496 reads (36%) | called by muse, mutect2, varscan2
- TJP3 | c.2445G>A p.A815= | Silent (SNP) | VAF 222/477 reads (47%) | catalogued as rs375043100; called by muse, mutect2, varscan2
- MUC19 | n.17744G>A | RNA (SNP) | VAF 140/705 reads (20%) | catalogued as rs910628156; called by muse, mutect2, varscan2
